Gene-level copy-number profile of tumor specimen TCGA-L5-A4OI-01A from TCGA case TCGA-L5-A4OI, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 79.9 years (29,190 days).
Specimen TCGA-L5-A4OI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.30852012-1282-4f8a-9674-c8b10df27c0b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OI-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/67874370-1b99-45f2-9c14-bb92d1c99251

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 2,530; copy number 2: 49,676; copy number 3: 6,049; copy number 4: 1,549.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OI-01A-11D-A25X-01): tumor purity 0.83, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:4,304,942–4,583,871, 1 gene (within-gene range 0–2): AL162718.1.
- chr6:4,381,211–4,955,551, 11 genes (within-gene range 0–2): AL162718.3, RNA5SP202, AL162718.2, LINC02533, AL133393.1, AL034376.1, KU-MEL-3, PSMC1P11, CDYL, AL356747.1, CDYL-AS1.
- chr20:14,884,250–15,022,958, 4 genes (within-gene range 0–1): MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
